CPTAC case C3L-00415 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d79d4830-d55e-4efe-bf00-9543461c7af4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 64.6 years (23,586 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,786 days (4.9 years); Progression or recurrence: yes; Days to last follow up: 1,786 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6.5 cm (a second GDC size field records 2.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 36; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 371 days (1.0 years); Disease response: With Tumor.
- Days to follow up: 699 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,063 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,427 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,786 days (4.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 356 days.
- Days to follow up: 1,786 days (4.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 69 kg; Height: 158 cm; BMI: 27.64; Comorbidities: Hypothyroidism.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 35; Cigarettes per day: 20; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 2009; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 35.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00415-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 347 mg.
- Sample C3L-00415-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 379 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00415-23: Section location: Left Lower Lobe; Percent tumor nuclei: 65; Percent necrosis: 15.
- Sample C3L-00415-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 602 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00415-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
